EXCEPTIONAL_RESPONDERS case ER-B0BO — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/07d215a1-a67e-4841-8cee-95edb400d020

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Extrahepatic bile duct; Classification of tumor: metastasis; Age at diagnosis: 67.9 years (24,796 days); Year of diagnosis: 2013; AJCC pathologic stage: Stage Tis; Prior malignancy: no; Days to last follow up: 954 days (2.6 years); Days to best overall response: 861 days (2.4 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Cisplatin; Days to treatment start: 652 days (1.8 years); Days to treatment end: 695 days (1.9 years).
   Treatment given: Therapeutic agents: Gemcitabine Hydrochloride; Days to treatment start: 652 days (1.8 years); Days to treatment end: 835 days (2.3 years).
   Treatment given: Therapeutic agents: Carboplatin; Days to treatment start: 709 days (1.9 years); Days to treatment end: 751 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 954 days (2.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 623 days (1.7 years); Days progression-free: 954 days (2.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0BO-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0BO-TTM1-A-2-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 50; Percent normal cells: 60; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
